Somatic mutation profile of tumor specimen MP2PRT-PATEWZ-TMP1-A (aliquot MP2PRT-PATEWZ-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATEWZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (664 days).
Specimen MP2PRT-PATEWZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7971af7-4057-423d-b674-2749ba0044e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATEWZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATEWZ-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b19f3c9-4878-465c-b727-d6b9b8424611

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 158/396 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS5 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 149/778 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1046679623, COSV53179186; called by muse, mutect2, varscan2
- CLDN2 | c.461A>G p.D154G | Missense Mutation (SNP) | VAF 176/667 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- FAIM2 | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 115/251 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KIR2DS4 | c.636G>A p.P212= | Silent (SNP) | VAF 59/88 reads (67%) | catalogued as rs543819286; called by muse, mutect2, varscan2
